Somatic mutation profile of tumor specimen TARGET-15-SJMPAL042792-09A.1 (aliquot TARGET-15-SJMPAL042792-09A.1-01D) from TARGET case TARGET-15-SJMPAL042792, project TARGET-ALL-P3 (Acute Lymphoblastic Leukemia - Phase III). Sex at birth: female; Vital status: Alive; Primary diagnosis: Acute lymphocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 4.2 years (1,527 days).
Specimen TARGET-15-SJMPAL042792-09A.1: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 4aa4c433-ae8b-463d-8d7a-71486a47f986.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-15-SJMPAL042792-14A (Bone Marrow Normal), aliquot TARGET-15-SJMPAL042792-14A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/43ef42f5-dee9-4fd8-8575-02f35e133bc4

The open-access MAF lists 9 somatic variants for this specimen: 5 protein-altering or splice-affecting, 2 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 4, Silent 2, Intron 2, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CHRM1 | c.782G>A p.R261H | Missense Mutation (SNP) | VAF 27/65 reads (42%) | SIFT tolerated (0.14); PolyPhen benign (0); catalogued as rs756528929, COSV61006252; called by muse, mutect2, varscan2
- DLL4 | c.1547G>A p.R516H | Missense Mutation (SNP) | VAF 15/59 reads (25%) | SIFT tolerated (0.22); PolyPhen benign (0.001); catalogued as rs774301166, COSV51061515; called by muse, mutect2, varscan2
- MACF1 | c.4193T>G p.L1398* | Nonsense Mutation (SNP) | VAF 22/112 reads (20%) | called by muse, mutect2, varscan2
- TAX1BP1 | c.1636C>A p.Q546K | Missense Mutation (SNP) | VAF 4/20 reads (20%) | SIFT tolerated (0.89); PolyPhen benign (0.045); called by muse, mutect2
- VWA3A | c.2261C>A p.P754H | Missense Mutation (SNP) | VAF 6/48 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); called by muse, mutect2
- DLGAP3 | c.639C>A p.G213= | Silent (SNP) | VAF 44/109 reads (40%) | called by muse, mutect2, varscan2
- THSD7A | c.1344C>T p.R448= | Silent (SNP) | VAF 11/53 reads (21%) | catalogued as rs776774107, COSV101448556; called by muse, mutect2, varscan2
- AC245033.1 | c.1174+738G>A | Intron (SNP) | VAF 11/32 reads (34%) | catalogued as rs989141339; called by muse, mutect2, varscan2
- LILRB1 | c.1800+349G>C | Intron (SNP) | VAF 6/41 reads (15%) | catalogued as rs747391159; called by muse, mutect2, varscan2
